National Lung Screening Trial (NLST) participant 217624 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 67 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: limited CT, but interpretable (motion artifact); technique as recorded on the form: 120 kVp, 100 mA, display field of view 38 cm, reconstruction filter GE Bone / GE Standard.
- T1 (day 510): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: limited CT, but interpretable (excessive quantum mottle or graininess); technique as recorded on the form: 120 kVp, 100 mA, display field of view 37 cm, reconstruction filter GE Bone / GE Standard.
- T2 (day 789): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: limited CT, but interpretable (excessive quantum mottle or graininess); technique as recorded on the form: 120 kVp, 70 mA, display field of view 40 cm, reconstruction filter GE Bone / GE Standard.

Abnormalities recorded by the reading radiologist on the CT screens (16 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 2: Emphysema.
- T0 abnormality 3: Other minor abnormality noted.
- T0 abnormality 4: Other minor abnormality noted.
- T0 abnormality 5: Other minor abnormality noted.
- T1 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 2: Emphysema.
- T1 abnormality 3: Other minor abnormality noted.
- T1 abnormality 4: Other minor abnormality noted.
- T1 abnormality 5: Pleural thickening or effusion.
- T2 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 2: Emphysema.
- T2 abnormality 3: Other minor abnormality noted.
- T2 abnormality 4: Other minor abnormality noted.
- T2 abnormality 5: Other minor abnormality noted.
- T2 abnormality 6: Pleural thickening or effusion.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,303.
